Somatic mutation profile of tumor specimen TCGA-L5-A4OH-01A (aliquot TCGA-L5-A4OH-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OH, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 71.7 years (26,180 days).
Specimen TCGA-L5-A4OH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14a0130c-a4bc-4b97-a0ce-6e2a2818a146.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OH-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OH-11A-11D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef053772-9e8c-4eb1-9cec-7887588b7934

The open-access MAF lists 129 somatic variants for this specimen: 101 protein-altering or splice-affecting, 22 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 22, Nonsense Mutation 5, Frame Shift Del 4, Intron 3, Splice Site 3, 3'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.1662+1G>A p.X554_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as rs587779535, CS000451, CS1412514, CS1412515, COSV58589650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.2002T>G p.L668V | Missense Mutation (SNP) | VAF 34/172 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV61957384, COSV61969153; called by muse, mutect2, varscan2
- ABCA1 | c.5753C>T p.T1918M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs752987110, COSV66067846; called by muse, mutect2, varscan2
- ABCB1 | c.2710T>G p.F904V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.626); catalogued as COSV99713464; called by muse, mutect2, varscan2
- ADAMTS1 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370561058; called by muse, mutect2, varscan2
- ADGRV1 | c.12487G>T p.G4163W | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101316547; called by muse, mutect2, varscan2
- BTN3A1 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | catalogued as COSV99176224; called by muse, mutect2
- C4BPB | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99699805, COSV99700183; called by muse, mutect2
- CAVIN2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV58423572; called by muse, mutect2, varscan2
- CD300C | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs774843981; called by muse, varscan2
- CDC7 | c.1272G>T p.L424F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319957; called by muse, mutect2
- CDH10 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV100049639, COSV52591372; called by muse, mutect2, varscan2
- CDKL2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs755711267, COSV56733569; called by muse, mutect2, varscan2
- CHST14 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); catalogued as rs1207935361, COSV60378824; called by muse, mutect2, varscan2
- CHST6 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.806); catalogued as rs765655457, COSV59999729; called by muse, mutect2, varscan2
- DFFA | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs145327902, COSV100986638, COSV65478031; called by muse, mutect2, varscan2
- DNAH10 | c.3565G>T p.D1189Y (on ENST00000409039; = p.D1128Y on NM_207437.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV68988918; called by muse, mutect2, varscan2
- ESRP1 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs1475520913, COSV64412405; called by muse, mutect2, varscan2
- FAM184A | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as rs752069529, COSV58859945; called by muse, mutect2, varscan2
- FAM214A | c.3073C>A p.L1025M | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs935626711, COSV55926913; called by muse, mutect2
- FER | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs1405560340; called by mutect2, varscan2
- FKBP15 | c.3595C>T p.R1199C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); catalogued as rs372719818; called by muse, mutect2, varscan2
- FMN2 | c.4865T>G p.I1622S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV60414894; called by muse, mutect2, varscan2
- GBF1 | c.2863G>T p.A955S (on ENST00000369983 / NM_001377137.1; = p.A954S on NM_004193.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.469); catalogued as COSV64142801; called by muse, mutect2, varscan2
- GJA1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.842); catalogued as rs778457698, COSV56997716, COSV56997996; called by muse, mutect2, varscan2
- GPR85 | c.959T>A p.F320Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51783729; called by muse, mutect2, varscan2
- GSTK1 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV64424105; called by muse, mutect2, varscan2
- HSPG2 | c.7684C>T p.P2562S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs755215244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPP5D | c.361G>A p.V121M (on ENST00000445964 / NM_001017915.3; = p.V120M on NM_005541.5) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs755468463; called by muse, mutect2, varscan2
- KCNMA1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1453880868, COSV54254333; called by muse, mutect2, varscan2
- MAST2 | c.3004C>T p.R1002* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs895275104; called by muse, mutect2, varscan2
- MMRN2 | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as rs750028252; called by muse, mutect2, varscan2
- MTIF2 | c.1898C>A p.S633Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55054099; called by muse, mutect2
- NEB | c.1882A>C p.K628Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.713); catalogued as COSV51202808; called by muse, mutect2, varscan2
- OSBPL5 | c.1403G>C p.R468P | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.546); catalogued as COSV99720920; called by muse, mutect2, varscan2
- PDCD4 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99701201; called by muse, mutect2, varscan2
- PDZD4 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557075362; called by muse, mutect2, varscan2
- PKHD1 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs186202437; called by muse, mutect2, varscan2
- PLA2G4E | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs184928850; called by muse, varscan2
- PLXNA4 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767480923; called by muse, mutect2, varscan2
- SAMHD1 | c.1223G>C p.R408P | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.491); catalogued as rs140417977, CM158860; called by muse, mutect2
- SLITRK5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.233); catalogued as rs1449242517, COSV61521420; called by muse, mutect2, varscan2
- TAF1L | c.4360C>T p.R1454C | Missense Mutation (SNP) | VAF 117/162 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs545988745, COSV54260912; called by muse, varscan2
- TDRD5 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs570123255, COSV54242186; called by muse, mutect2, varscan2
- TENM4 | c.4111C>T p.R1371C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374934640; called by muse, mutect2, varscan2
- USH2A | c.4817A>C p.K1606T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV100244768; called by muse, mutect2, varscan2
- VPS13B | c.6587G>A p.S2196N | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as rs751998053, COSV62132251; called by muse, mutect2, varscan2
- ZNF616 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs777378939, COSV57509555; called by muse, mutect2, varscan2
- ABL1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACD | c.764C>T p.S255F (on ENST00000620338; = p.S166F on NM_022914.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADAM17 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ARID1B | c.6176C>A p.P2059H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP8B2 | c.877G>A p.G293S (on ENST00000672630; = p.G260S on NM_001005855.2) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCL7B | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BIRC6 | c.12176_12186del p.E4059Gfs*23 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- CCDC124 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CDH2 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CES3 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CFAP46 | c.6118G>A p.A2040T | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CTNNA2 | c.2084G>C p.S695T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP2U1 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- DCAF6 | c.1921C>T p.H641Y (on ENST00000312263 / NM_001349778.1; = p.H661Y on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DENND2C | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ELF3 | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 25/38 reads (66%) | called by muse, mutect2, varscan2
- EP300 | c.3387G>T p.W1129C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ERBB4 | c.2212G>T p.V738L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- FKTN | c.998T>C p.L333S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GABRA4 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- GOLGA2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GRK5 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HDGFL2 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IL5RA | c.433C>A p.R145S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2
- JHY | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF18B | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- LRP4 | c.1739A>G p.E580G | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYST | c.7139C>A p.A2380D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAPK14 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2
- MDN1 | c.11060T>C p.L3687P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPPED2 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUSK | c.2178A>T p.L726F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OFD1 | c.1966G>T p.V656F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2
- OR11H4 | c.708del p.Q237Rfs*31 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- PCARE | c.1509T>G p.C503W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PCDH15 | c.5168C>A p.P1723H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2
- PCDHGB1 | c.1173del p.E391Dfs*11 | Frame Shift Del (DEL) | VAF 13/24 reads (54%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.10987G>T p.D3663Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, varscan2
- PRKAR1B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- PRKAR2B | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROX1 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPS19 | c.12_14delinsAA p.T5Mfs*2 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by pindel, varscan2*
- SDHA | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- SGCG | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- SPRR2B | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- STAB2 | c.4013C>T p.A1338V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SUCO | c.3118G>A p.D1040N | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SUGCT | c.312A>G p.K104= | Splice Region (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- SUPT5H | c.625-1G>A p.X209_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- SYNE1 | c.21656+2_21656+5del p.X7219_splice (on ENST00000367255 / NM_182961.4; = p.X7148_splice on NM_033071.3) | Splice Site (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- TRAF3IP2 | c.284A>C p.Q95P | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZC3H13 | c.4547C>A p.A1516D (on ENST00000242848 / NM_001330565.2; = p.A1517D on NM_015070.6) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF585B | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 73/86 reads (85%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ATRNL1 | c.3477G>T p.T1159= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs868945749, COSV100370008; called by muse, mutect2
- BRWD3 | c.4585C>A p.R1529= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- CASQ2 | c.504T>C p.I168= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs771992236; called by muse, mutect2, varscan2
- CHRND | c.9G>T p.G3= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- CHST4 | c.591C>T p.N197= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- EGR2 | c.9C>A p.T3= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- EPG5 | c.1494C>T p.I498= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, varscan2
- EVC | c.231G>A p.S77= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs140615894, COSV53833118; ClinVar: likely benign; called by muse, mutect2, varscan2
- FDXACB1 | c.1413C>A p.I471= | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- GP1BB | c.6C>T p.G2= | Silent (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- GRIK2 | c.18G>A p.P6= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs776282459, COSV100025489, COSV59758434; called by muse, mutect2
- GRIK4 | c.678C>T p.T226= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- HUWE1 | c.3405T>A p.V1135= | Silent (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- MAU2 | c.399G>A p.A133= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs764595627, COSV53233709; called by muse, mutect2, varscan2
- MYO7B | c.2511C>A p.V837= | Silent (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- MYRIP | c.315C>T p.C105= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs781036175, COSV56861134; called by muse, mutect2, varscan2
- PCDHA2 | c.2253G>A p.S751= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs782152702, COSV65371636; called by muse, mutect2, varscan2
- PRKD1 | c.2266A>C p.R756= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100119150; called by muse, mutect2, varscan2
- PTGS2 | c.1185C>T p.Y395= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as rs1558247881, COSV66569213; called by muse, mutect2, varscan2
- SCYL3 | c.642C>A p.L214= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100884323; called by muse, mutect2
- SLC4A7 | c.3123C>T p.F1041= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- SYVN1 | c.147G>A p.Q49= | Silent (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3926G>A | 3'UTR (SNP) | VAF 26/69 reads (38%) | catalogued as COSV57059726; called by muse, mutect2, varscan2
- LINC02843 | n.318C>T | RNA (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- RIMS2 | c.698+52990G>A | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as rs377178152, COSV51684277; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2112G>A | Intron (SNP) | VAF 29/74 reads (39%) | catalogued as rs1404067096; called by muse, mutect2, varscan2
- WDR43 | c.607-332G>T | Intron (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZNF99 | c.*581A>G | 3'UTR (SNP) | VAF 14/33 reads (42%) | catalogued as COSV68055986; called by muse, mutect2, varscan2
